Gene-level copy-number profile of tumor specimen ALCH-AE8L-TTP1-A from ALCHEMIST case ALCH-AE8L, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.1 years (25,590 days).
Specimen ALCH-AE8L-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e2a6c17c-4fcc-4ea6-b920-375aad82cf65.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE8L-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/ec0d6afb-0beb-4534-9fe3-2c81d019f57d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 63; copy number 1: 3,454; copy number 2: 54,118; copy number 3: 738; copy number 4: 2; copy number 5: 11; copy number 7: 3; copy number 12: 1; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,668,778–28,719,353, 2 genes: GMEB1, AL645729.1.
- chr1:28,812,142–28,871,267, 1 gene (within-gene range 0–1): OPRD1.
- chr1:111,989,770–111,998,842, 1 gene: LINC01750.
- chr1:175,877,343–175,880,468, 1 gene: LINC01657.
- chr2:90,309,230–91,621,421, 7 genes (within-gene range 0–1): AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1.
- chr2:91,686,102–91,723,605, 2 genes: AC027612.2, NKAIN1P2.
- chr2:218,326,889–218,357,966, 3 genes (within-gene range 0–1): CATIP-AS2, MIR6810, RPL19P5.
- chr2:218,382,029–218,396,894, 1 gene: SLC11A1.
- chr4:49,203,171–49,203,726, 1 gene: AC118282.3.
- chr4:151,027,090–151,104,642, 3 genes (within-gene range 0–2): AK4P6, RPS3A, SNORD73B.
- chr4:151,103,827–151,103,891, 1 gene (within-gene range 0–2): SNORD73A.
- chr6:37,815,777–37,819,218, 1 gene: AL121574.1.
- chr7:140,518,420–140,673,993, 4 genes (within-gene range 0–2): DENND2A, Y_RNA, AC006452.1, RN7SL771P.
- chr7:149,102,784–149,126,324, 2 genes (within-gene range 0–2): ZNF425, RN7SL521P.
- chr11:637,269–640,706, 1 gene: DRD4.
- chr11:694,438–727,727, 3 genes (within-gene range 0–2): EPS8L2, TMEM80, AP006621.4.
- chr11:1,256,605–1,256,670, 1 gene (within-gene range 0–7): MIR6744.
- chr12:48,813,794–48,828,941, 1 gene: CACNB3.
- chr12:53,251,251–53,254,406, 1 gene: MFSD5.
- chr14:106,831,767–106,879,812, 7 genes: IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr16:46,469,341–46,569,097, 2 genes: ANKRD26P1, RNU6-845P.
- chr16:47,004,513–47,035,385, 2 genes: AC018845.1, AC018845.2.
- chr17:80,333,841–80,342,058, 2 genes (within-gene range 0–2): AC124319.2, AC124319.3.
- chr20:31,547,412–31,581,214, 5 genes: MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P.
- chr22:18,029,385–18,078,884, 2 genes (within-gene range 0–2): LINC01634, AC016027.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:787,115–798,281, 2 genes, copy number 12–13 (within-gene range 3–13): CEND1, SLC25A22.
- chr11:1,223,066–1,262,172, 2 genes, copy number 7 (within-gene range 0–7): MUC5B, MUC5B-AS1.
- chr17:81,303,771–81,309,248, 1 gene, copy number 5: LINC00482.
- chr17:81,339,183–81,345,966, 1 gene, copy number 7 (within-gene range 6–7): AC027601.5.
- chr20:62,302,093–62,427,539, 10 genes, copy number 5: ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL.

Autosomal genes at a single copy (total copy number 1): 3,405. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
